Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0FF, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0FF-01A (Primary Tumor).

TSS Patient ID

Case #: DOB Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement: Anatomic Site: **Left Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **OCT**

Container: **block** Type of Procurement: **surgery** Grade: **2**

T Stage: **1** N Stage: **0** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

1CD-0-3

carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9 lw 10/21/11

Source: NCI Genomic Data Commons file e15217b1-3646-4603-89b9-842c4611e7c9 (TCGA-AN-A0FF.9B4BA15D-A071-4213-AD2C-075A04ED48CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).